Somatic mutation profile of tumor specimen 0DKDDD from CCDI case PBBYCL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,459 days).
Specimen 0DKDDD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc4a1b5a-403f-467b-9dec-8d1d2ac1cbd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKDC1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e84569f-5b45-4b30-9406-f09573ebde00

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHA3 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as COSV65366265; called by muse, mutect2
- NLK | c.644+1G>A p.X215_splice | Splice Site (SNP) | VAF 34/1348 reads (3%) | called by muse, mutect2
- QKI | c.371G>C p.R124P | Missense Mutation (SNP) | VAF 66/1959 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
